Somatic mutation profile of tumor specimen MMRF_2122_3_BM_CD138pos (aliquot MMRF_2122_3_BM_CD138pos_T1_KHS5U_L14409) from MMRF case MMRF_2122, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,480 days).
Specimen MMRF_2122_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87c1691d-777a-4570-b3ac-e8ac69d21460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2122_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2122_2_PB_Whole_C1_KHS5U_L08141; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a506e946-ed72-41f5-aa2a-0ba707bddfac

The open-access MAF lists 70 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 18, Silent 9, 5'Flank 3, Intron 3, Nonsense Mutation 2, Splice Region 2, 5'UTR 2, Frame Shift Del 1, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICRA | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1488443734; called by muse, mutect2, varscan2
- BIRC6 | c.9130A>G p.S3044G | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs144025041, COSV101429488; called by muse, mutect2, varscan2
- CCT8L2 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1461798692; called by muse, mutect2, varscan2
- CENPM | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 62/75 reads (83%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs774792724; called by muse, mutect2, varscan2
- COG1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs865958513; called by muse, mutect2
- ERCC3 | c.1155C>G p.D385E | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.161); catalogued as rs371396764; called by muse, mutect2, varscan2
- GPRASP2 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59990351; called by muse, mutect2, varscan2
- H1-5 | c.125del p.P42Qfs*5 | Frame Shift Del (DEL) | VAF 111/325 reads (34%) | catalogued as rs1387749224; called by pindel, varscan2
- HERC2 | c.10585C>T p.P3529S | Missense Mutation (SNP) | VAF 117/275 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs754366545; called by muse, mutect2, varscan2
- IGHV2-70 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs769646259; called by muse, varscan2
- LRIG3 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1046332185; called by muse, mutect2, varscan2
- MAS1L | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as rs768922382, COSV65809104; called by muse, mutect2, varscan2
- TELO2 | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 164/332 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1204132834; called by muse, mutect2, varscan2
- VPS13D | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 67/167 reads (40%) | catalogued as rs1216395626; called by muse, mutect2, varscan2
- ATP2A3 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACYBP | c.271A>T p.I91F | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CTSF | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.8276G>T p.G2759V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GFUS | c.261+8A>T | Splice Region (SNP) | VAF 18/58 reads (31%) | called by muse, varscan2
- IGHV1-69D | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- LRRTM4 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 87/189 reads (46%) | called by muse, mutect2, varscan2
- MTHFD1 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH1 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR2A14 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PIGL | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKDC | c.11320A>T p.I3774F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- RESF1 | c.2633A>G p.E878G | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, varscan2
- RESF1 | c.2707A>G p.T903A | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, varscan2
- SAR1B | c.179-6A>G | Splice Region (SNP) | VAF 126/255 reads (49%) | called by muse, mutect2, varscan2
- SEMA6C | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2
- TEAD2 | c.1069_1077+11del p.X357_splice | Splice Site (DEL) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- TMPRSS5 | c.442T>A p.C148S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.10042C>T p.P3348S | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.6087T>C p.P2029= | Silent (SNP) | VAF 104/243 reads (43%) | called by muse, mutect2, varscan2
- CALCR | c.819A>G p.Q273= (on ENST00000649521 / NM_001164737.2; = p.Q257= on NM_001742.4) | Silent (SNP) | VAF 97/259 reads (37%) | called by muse, mutect2, varscan2
- EXD1 | c.301C>T p.L101= | Silent (SNP) | VAF 126/307 reads (41%) | called by muse, mutect2, varscan2
- GIGYF2 | c.3885G>T p.T1295= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs774560951, COSV65246805; called by muse, mutect2, varscan2
- IGLV3-16 | c.162C>T p.Y54= | Silent (SNP) | VAF 82/102 reads (80%) | catalogued as rs529492618; called by muse, mutect2, varscan2
- LRP3 | c.1335C>T p.D445= | Silent (SNP) | VAF 100/206 reads (49%) | catalogued as rs762664449; called by muse, varscan2
- NYNRIN | c.5029C>T p.L1677= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs1462836405; called by muse, mutect2, varscan2
- STK17A | c.36C>T p.S12= | Silent (SNP) | VAF 77/173 reads (45%) | catalogued as rs1563141110, COSV60046749; called by muse, mutect2, varscan2
- WDR24 | c.1326C>T p.S442= (on ENST00000248142; = p.S312= on NM_032259.4) | Silent (SNP) | VAF 117/249 reads (47%) | called by muse, mutect2, varscan2
- AC010928.1 | n.79C>T | RNA (SNP) | VAF 65/121 reads (54%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+33342T>C | Intron (SNP) | VAF 73/148 reads (49%) | called by muse, mutect2, varscan2
- ARMH4 | c.*1361T>G | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2
- BAALC | chr8:103229966 T>A | 3'Flank (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021492 C>G | 5'Flank (SNP) | VAF 129/268 reads (48%) | catalogued as COSV55846308, COSV55846472; called by muse, mutect2, varscan2
- CHRNA4 | c.*144G>T | 3'UTR (SNP) | VAF 58/117 reads (50%) | called by muse, mutect2, varscan2
- ETV1 | c.*478C>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | catalogued as rs756393569; called by muse, mutect2
- IGHJ6 | chr14:105863437 A>T | 5'Flank (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
- LIMCH1 | c.*289T>C | 3'UTR (SNP) | VAF 18/53 reads (34%) | catalogued as rs1462748547; called by muse, mutect2
- NINJ2 | c.-32C>T | 5'UTR (SNP) | VAF 82/179 reads (46%) | catalogued as rs747050059, COSV59324291; called by muse, mutect2, varscan2
- P2RY2 | c.*836G>T | 3'UTR (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-2301C>T | Intron (SNP) | VAF 100/249 reads (40%) | called by muse, mutect2, varscan2
- POR | c.*225G>A | 3'UTR (SNP) | VAF 44/86 reads (51%) | catalogued as rs375406404; called by muse, mutect2, varscan2
- RNF145 | c.*1075T>C | 3'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2
- RNF145 | c.*1073T>C | 3'UTR (SNP) | VAF 60/132 reads (45%) | called by muse, mutect2
- SPA17 | c.*54T>C | 3'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- SPA17 | c.*168del | 3'UTR (DEL) | VAF 28/76 reads (37%) | called by pindel, varscan2
- SPA17 | c.*247A>G | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, varscan2
- SPA17 | c.*599T>A | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- SPA17 | c.*2519T>G | 3'UTR (SNP) | VAF 59/142 reads (42%) | called by muse, varscan2
- SPA17 | c.*2670C>T | 3'UTR (SNP) | VAF 77/168 reads (46%) | called by muse, varscan2
- SST | c.*108T>C | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TBX5 | c.*528C>A | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- TCF4 | c.287-9002C>T | Intron (SNP) | VAF 32/75 reads (43%) | catalogued as rs146003827; called by muse, mutect2, varscan2
- TMBIM6 | c.*1530C>T | 3'UTR (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- TXNRD3 | chr3:126655123 G>T | 5'Flank (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- UBAC2 | c.-51T>C | 5'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as rs1189977107; called by muse, mutect2, varscan2
- ZNF764 | c.*1217T>C | 3'UTR (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
